Somatic mutation profile of tumor specimen TCGA-33-AASL-01A (aliquot TCGA-33-AASL-01A-11D-A401-08) from TCGA case TCGA-33-AASL, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 57.3 years (20,940 days).
Specimen TCGA-33-AASL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0decaeeb-8553-4d53-9cc9-e06600558f3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-AASL-11A (Solid Tissue Normal), aliquot TCGA-33-AASL-11A-11D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14872477-5bb7-4237-98dd-8605d4110a0b

The open-access MAF lists 336 somatic variants for this specimen: 253 protein-altering or splice-affecting, 78 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 78, Nonsense Mutation 13, Frame Shift Del 7, Splice Region 2, Splice Site 2, 5'Flank 2, Frame Shift Ins 1, Intron 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.1143del p.T382Lfs*20 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs1064796125; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.182A>G p.H61R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99714711; called by muse, mutect2, varscan2
- AC244197.3 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV61713481; called by muse, mutect2, varscan2
- ACP7 | c.1278G>C p.W426C | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100488638; called by muse, varscan2
- ADAMTS12 | c.2990C>A p.P997H | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779162780, COSV100711767; called by muse, mutect2, varscan2
- ADGRF4 | c.458C>G p.S153* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV99349151; called by muse, mutect2, varscan2
- ADGRV1 | c.12915G>T p.M4305I | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1435801636, COSV101316659; called by muse, mutect2, varscan2
- ALDH1L1 | c.2408A>G p.E803G | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99857644; called by muse, mutect2, varscan2
- ALMS1 | c.5515C>G p.Q1839E | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs1252756270, COSV100044048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMER3 | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs866752130, COSV100366991; called by muse, mutect2, varscan2
- ANKRD35 | c.2008C>T p.R670* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | catalogued as COSV100841874; called by muse, mutect2
- APC | c.5815G>T p.D1939Y | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as COSV57384864, COSV99970817; called by muse, mutect2, varscan2
- ARHGEF2 | c.1914G>T p.R638S (on ENST00000361247 / NM_001162383.2; = p.R610S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58115406; called by muse, mutect2, varscan2
- ASB12 | c.786A>T p.Q262H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as COSV100744856; called by muse, mutect2, varscan2
- ASB17 | c.84A>T p.K28N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV52411368, COSV99408100; called by muse, mutect2, varscan2
- ATG4C | c.399G>T p.W133C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755966686, COSV100508624; called by muse, mutect2, varscan2
- ATR | c.7201A>G p.M2401V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100638687; called by muse, mutect2, varscan2
- AVPR2 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.204); catalogued as COSV100509717; called by muse, mutect2, varscan2
- BANK1 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs199571267, COSV100536998, COSV59839737; called by muse, mutect2, varscan2
- BBS10 | c.606G>C p.M202I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as COSV99675731; called by muse, mutect2
- BCL9L | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV100600282; called by muse, mutect2, varscan2
- BEX5 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV100375100; called by muse, mutect2, varscan2
- BRINP2 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as COSV100838529, COSV64175535; called by muse, mutect2, varscan2
- BRWD3 | c.4364G>T p.S1455I | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV100956643, COSV64749586; called by muse, mutect2, varscan2
- BTRC | c.1186A>T p.M396L (on ENST00000370187 / NM_033637.4; = p.M360L on NM_003939.5) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV100927945; called by muse, mutect2, varscan2
- C2orf16 | c.854T>A p.I285K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as COSV101284446; called by muse, mutect2, varscan2
- C4orf50 | c.361G>T p.A121S (on ENST00000324058; = p.A1353S on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100135581, COSV100136242; called by muse, mutect2, varscan2
- CACNG4 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100047983; called by muse, mutect2, varscan2
- CARMIL1 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100278977, COSV99051893; called by muse, mutect2, varscan2
- CC2D1B | c.2334C>G p.I778M | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99430401; called by muse, mutect2
- CCAR1 | c.2824G>C p.E942Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99771498; called by muse, mutect2, varscan2
- CDH10 | c.1923G>T p.E641D | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.582); catalogued as COSV100053450; called by muse, varscan2
- CDH3 | c.1085G>T p.W362L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99869404; called by mutect2, varscan2
- CELSR2 | c.2623A>T p.T875S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99604948; called by muse, mutect2, varscan2
- CHRM2 | c.142A>T p.I48F | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as COSV100282121; called by muse, mutect2, varscan2
- CLIP2 | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1554313003, COSV99792515; called by muse, mutect2, varscan2
- CNGB3 | c.411A>T p.K137N | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV100183261; called by muse, mutect2, varscan2
- CNTNAP5 | c.2912G>T p.G971V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101444361; called by muse, mutect2, varscan2
- COL11A2 | c.444G>A p.K148= | Splice Region (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100554622; called by muse, mutect2
- COPB2 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV100300949; called by muse, mutect2, varscan2
- CR1L | c.834G>T p.W278C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372130537; called by muse, mutect2, varscan2
- CR1L | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as rs777533568, COSV99688143; called by muse, mutect2, varscan2
- CRISPLD1 | c.1048G>T p.G350C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438583936, COSV100082543; called by muse, mutect2, varscan2
- CRYZ | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV100558744, COSV61718421; called by muse, mutect2, varscan2
- CSMD3 | c.10825C>A p.L3609M (on ENST00000297405 / NM_001363185.1; = p.L3440M on NM_052900.3) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV99850970; called by muse, mutect2, varscan2
- CTAGE1 | c.44T>A p.V15E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101194718; called by muse, mutect2, varscan2
- DCX | c.1036C>A p.H346N (on ENST00000636035 / NM_001195553.2; = p.H341N on NM_000555.3) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.09); catalogued as COSV100576811; called by muse, mutect2, varscan2
- DCX | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100576813; called by muse, mutect2, varscan2
- DDX39B | c.1197C>G p.I399M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.202); catalogued as COSV100871100; called by mutect2, varscan2
- DGKG | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99404610; called by muse, mutect2, varscan2
- DIAPH2 | c.2888C>A p.T963N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100235893; called by muse, mutect2, varscan2
- DISC1 | c.176del p.P59Qfs*50 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs1311795156, COSV54407945; called by mutect2, pindel, varscan2
- DMD | c.3045C>G p.S1015R | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as COSV100823428; called by muse, mutect2, varscan2
- DMRT1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101206729; called by muse, mutect2, varscan2
- DMTF1 | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); catalogued as COSV100487545; called by muse, mutect2, varscan2
- DNAH9 | c.5738del p.A1913Vfs*27 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as COSV52374077; called by mutect2, pindel, varscan2
- DNAJB11 | c.344T>C p.F115S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.965); catalogued as rs1209888358, COSV99408775; called by mutect2, varscan2
- DNAJC2 | c.1089G>C p.W363C | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.921); catalogued as COSV99972027; called by muse, mutect2, varscan2
- DRD3 | c.872C>A p.A291E | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.573); catalogued as rs201876283, COSV55680023, COSV99879740; called by muse, mutect2, varscan2
- DTX4 | c.1457A>T p.H486L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV99916043; called by muse, mutect2, varscan2
- ECEL1 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV58812782; called by muse, mutect2, varscan2
- EIF4A2 | c.586C>G p.Q196E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV99961415; called by muse, mutect2
- ELAVL1 | c.328A>T p.I110F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100688544; called by muse, mutect2, varscan2
- EPHA10 | c.2341G>T p.D781Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs202083700, COSV100361820; called by muse, mutect2, varscan2
- EPHA3 | c.2149C>A p.Q717K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100349521; called by muse, mutect2, varscan2
- ERBB2 | c.986A>T p.Q329L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV99509378; called by muse, mutect2, varscan2
- ERBB3 | c.1922A>T p.H641L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV99918097; called by muse, mutect2, varscan2
- ETNPPL | c.1371+2T>A p.X457_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99625730; called by muse, mutect2, varscan2
- FAM118B | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100796939; called by muse, mutect2, varscan2
- FAM133A | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as rs1236778384, COSV100220750; called by muse, mutect2, varscan2
- FAM217B | c.410A>T p.K137I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV100674704; called by muse, mutect2, varscan2
- FAM47C | c.841C>A p.H281N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV100793004; called by muse, mutect2, varscan2
- FAT1 | c.5801G>T p.G1934V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499681, COSV71674932; called by muse, mutect2, varscan2
- FAT1 | c.5800G>T p.G1934C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499682; called by muse, mutect2, varscan2
- FBXO38 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99694102; called by muse, mutect2, varscan2
- FBXO47 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100960917; called by muse, mutect2, varscan2
- FTHL17 | c.301A>T p.M101L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV100784458; called by muse, mutect2, varscan2
- FZD1 | c.1870G>T p.G624C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55310557, COSV99842837; called by muse, mutect2, varscan2
- GNL2 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100895056; called by muse, mutect2, varscan2
- GPA33 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100901314; called by muse, mutect2, varscan2
- GPR50 | c.1172G>T p.R391I | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV99506829; called by muse, mutect2, varscan2
- GPR89A | c.998A>G p.Q333R | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.096); catalogued as COSV100572549; called by muse, mutect2, varscan2
- GRID1 | c.2270C>A p.S757* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100027030, COSV60061780; called by muse, mutect2, varscan2
- GRIN2D | c.2004C>G p.I668M | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99617081; called by muse, mutect2, varscan2
- GRK5 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.067); catalogued as COSV100963318; called by muse, mutect2, varscan2
- H2BC12 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV63617032, COSV63617111; called by muse, mutect2, varscan2
- HBD | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99496920; called by muse, mutect2, varscan2
- HDAC5 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs747855581, COSV52241986; called by muse, mutect2, varscan2
- HDGFL1 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100014757; called by muse, mutect2, varscan2
- HEATR5B | c.4905G>T p.Q1635H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV99250396; called by muse, mutect2
- HECW2 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV99649367; called by muse, mutect2, varscan2
- HELZ | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV100699116; called by muse, mutect2
- HIF3A | c.1519C>A p.Q507K (on ENST00000377670 / NM_152795.4; = p.Q438K on NM_022462.4) | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs1370999284, COSV99356135; called by muse, mutect2, varscan2
- HMGN5 | c.251A>T p.E84V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100815040; called by muse, mutect2
- HP | c.1018T>C p.C340R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577669; called by muse, mutect2, varscan2
- HTATSF1 | c.1116C>A p.F372L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99511959; called by muse, mutect2, varscan2
- IGFN1 | c.2651G>C p.C884S (on ENST00000295591 / NM_001367841.1; = p.C3341S on NM_001164586.2) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.517); catalogued as COSV99813739; called by muse, mutect2
- INSIG2 | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV99830689; called by muse, mutect2, varscan2
- ITGA8 | c.695G>T p.S232I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1441770442, COSV100959881, COSV65235595; called by muse, mutect2, varscan2
- KCNK2 | c.966G>T p.V322= (on ENST00000444842 / NM_001017425.3; = p.V307= on NM_014217.4) | Splice Region (SNP) | VAF 16/75 reads (21%) | catalogued as rs1171141189, COSV101222386; called by muse, mutect2, varscan2
- KCNN2 | c.901G>T p.V301F (on ENST00000264773; = p.V513F on NM_021614.4) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV53301691, COSV99300920; called by muse, mutect2, varscan2
- KCTD20 | c.671A>G p.H224R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1484640834, COSV99536304; called by muse, mutect2
- KCTD8 | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as rs1173087794, COSV100760225; called by muse, mutect2, varscan2
- KIAA1109 | c.10504G>A p.D3502N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV99191612; called by muse, mutect2, varscan2
- KIAA1210 | c.3286G>T p.E1096* | Nonsense Mutation (SNP) | VAF 23/157 reads (15%) | catalogued as COSV101274451; called by muse, mutect2, varscan2
- KIF16B | c.2965A>G p.K989E | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV100735005; called by muse, mutect2, varscan2
- KIF4B | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101469426; called by muse, mutect2, varscan2
- KIFBP | c.1452G>A p.M484I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs762099157, COSV100741438, COSV62832137; called by muse, mutect2, varscan2
- KLRK1 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV53698750, COSV99555300; called by muse, mutect2, varscan2
- KRT74 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs775208348, COSV99977331; called by muse, mutect2, varscan2
- LIG1 | c.2372A>T p.Q791L | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs1394295086, COSV99619440; called by muse, mutect2, varscan2
- LPA | c.3817G>T p.D1273Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1434674471, COSV100308290; called by muse, mutect2, varscan2
- LRRC8E | c.1564C>A p.L522I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100143181; called by muse, mutect2
- LRRTM1 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV99703357; called by muse, mutect2, varscan2
- LVRN | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); catalogued as rs1323659892, COSV100773709; called by muse, mutect2, varscan2
- MAGEB3 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.047); catalogued as COSV100854839, COSV64396902; called by muse, mutect2, varscan2
- MAGEB6 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.51); catalogued as COSV66872216; called by muse, mutect2, varscan2
- MCF2 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs766980072, COSV100645253; called by muse, mutect2, varscan2
- MEIOC | c.1855C>G p.P619A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV100740313; called by muse, mutect2
- MMP14 | c.1072G>C p.G358R | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.278); catalogued as COSV100314352; called by muse, mutect2, varscan2
- MOCS3 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99724534; called by muse, mutect2, varscan2
- MROH9 | c.1564G>T p.D522Y | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63009744; called by muse, mutect2, varscan2
- MSH2 | c.1933C>G p.Q645E | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs267607982, COSV51884925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTUS1 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV100030202; called by muse, mutect2, varscan2
- MUC16 | c.13088C>A p.T4363N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.446); catalogued as COSV101202081; called by muse, mutect2, varscan2
- MVB12B | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100753228; called by muse, mutect2, varscan2
- MXD3 | c.221A>T p.K74M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100293829; called by muse, varscan2
- NAP1L2 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100999244; called by muse, mutect2, varscan2
- NBAS | c.1467A>G p.I489M | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as COSV99872037; called by muse, mutect2, varscan2
- NCOA1 | c.3108G>C p.M1036I | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56045416, COSV99947292; called by muse, mutect2
- NDUFAF2 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99681848; called by muse, mutect2, varscan2
- NOP2 | c.1765A>T p.N589Y (on ENST00000322166 / NM_001258308.2; = p.N585Y on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100351413; called by muse, mutect2, varscan2
- NOX5 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV99534944; called by muse, mutect2
- NRK | c.335C>A p.A112E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305539961, COSV99689413; called by muse, mutect2
- NRROS | c.219G>C p.W73C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV100145665; called by muse, mutect2, varscan2
- NUMA1 | c.3425A>G p.Q1142R | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV100706699; called by muse, mutect2, varscan2
- NUP205 | c.3691-2A>T p.X1231_splice | Splice Site (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99607735; called by muse, mutect2, varscan2
- NXF3 | c.375T>A p.N125K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV101222110; called by muse, mutect2, varscan2
- OGT | c.3098C>A p.P1033H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV101033246; called by muse, mutect2, varscan2
- OPHN1 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 27/121 reads (22%) | catalogued as COSV100830860, COSV62784695; called by muse, mutect2, varscan2
- OPN5 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs751407060, COSV55247797; called by muse, mutect2, varscan2
- OR10A4 | c.87T>A p.F29L | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101139634; called by muse, mutect2, varscan2
- OR10S1 | c.762del p.C255Afs*39 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs772207982, COSV73342953; called by mutect2, pindel, varscan2
- OR2F2 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV101283864; called by muse, mutect2, varscan2
- OR2T35 | c.287T>A p.L96Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.615); catalogued as rs1420943395, COSV100442422; called by muse, mutect2, varscan2
- OR4D10 | c.546C>A p.H182Q | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV101597037; called by muse, mutect2, varscan2
- OR52E2 | c.704G>C p.R235P | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779367327, COSV100384963; called by muse, mutect2, varscan2
- OR5M11 | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101602066, COSV101602077; called by muse, mutect2
- OR5T2 | c.674C>A p.A225D | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs1235218779, COSV100507122; called by muse, mutect2, varscan2
- OR7D2 | c.594G>T p.L198F | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.009); catalogued as COSV100713096; called by muse, mutect2, varscan2
- OR8H2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV100542527; called by muse, varscan2
- OR8I2 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.821); catalogued as COSV100136290, COSV56166480; called by muse, mutect2, varscan2
- OR9Q1 | c.821C>A p.S274Y | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59039266; called by muse, mutect2, varscan2
- OSBPL8 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs747901774, COSV99675734; called by muse, mutect2, varscan2
- PAMR1 | c.1237G>A p.E413K (on ENST00000619888 / NM_001001991.3; = p.E430K on NM_015430.4) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.67); catalogued as rs143939242, COSV53517450; called by muse, mutect2, varscan2
- PARP14 | c.4019C>T p.P1340L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV101506307, COSV101506370; called by muse, mutect2
- PCDHB11 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100696916; called by muse, mutect2, varscan2
- PCDHB8 | c.22A>G p.I8V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV99177557; called by muse, varscan2
- PCDHGA2 | c.1081C>T p.L361F | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV99548896; called by muse, mutect2, varscan2
- PCDHGA7 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 41/170 reads (24%) | catalogued as COSV99548900; called by muse, mutect2, varscan2
- PCNX2 | c.3823A>G p.I1275V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as COSV99269927; called by muse, mutect2, varscan2
- PCSK2 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.865); catalogued as rs1349677688, COSV52740074; called by muse, mutect2, varscan2
- PDHA1 | c.821G>T p.R274I | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.842); catalogued as COSV100135992; called by muse, mutect2, varscan2
- PFKP | c.1376A>T p.K459I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV101127579; called by muse, mutect2, varscan2
- PIK3C2A | c.334A>T p.K112* | Nonsense Mutation (SNP) | VAF 27/122 reads (22%) | catalogued as COSV56400192, COSV56405356, COSV99791378; called by muse, mutect2, varscan2
- PIKFYVE | c.3265C>T p.P1089S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100011605, COSV100011627; called by muse, mutect2, varscan2
- PKLR | c.528G>C p.E176D | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV100713081; called by muse, mutect2, varscan2
- PLEKHG2 | c.3104C>T p.T1035I | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as rs141423271; called by muse, mutect2, varscan2
- PLSCR5 | c.499C>G p.Q167E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101494517; called by muse, varscan2
- PNMA3 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100937685; called by muse, mutect2, varscan2
- POLQ | c.4765A>G p.R1589G | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1278781404, COSV99953150; called by muse, mutect2, varscan2
- PPP2R5E | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV61743918; called by muse, mutect2, varscan2
- PPWD1 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99731656; called by muse, mutect2, varscan2
- PRAMEF4 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99339441, COSV99340342; called by muse, mutect2, varscan2
- PRKD1 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59572410; called by muse, mutect2, varscan2
- PRUNE2 | c.2860C>A p.L954I | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100945265, COSV100945319; called by muse, mutect2, varscan2
- PTCD3 | c.19G>C p.V7L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99606719; called by muse, mutect2, varscan2
- PTPRB | c.5222C>T p.A1741V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs113079289, COSV99719365; called by muse, mutect2, varscan2
- PYCARD | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs1317142260, COSV99910981; called by muse, mutect2, varscan2
- RALGAPB | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV53437534, COSV99485980; called by muse, mutect2, varscan2
- RASAL2 | c.2681T>C p.L894S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as COSV100862981; called by muse, mutect2, varscan2
- RBMX2 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.219); catalogued as COSV100564885; called by muse, mutect2, varscan2
- REV3L | c.439A>T p.N147Y | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725746; called by muse, mutect2, varscan2
- RPL10 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV99185826, COSV99186406; called by muse, mutect2, varscan2
- RSPH6A | c.2098A>T p.T700S | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99537459; called by muse, mutect2, varscan2
- SATB1 | c.2153A>G p.E718G | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100113524; called by muse, mutect2
- SCN9A | c.1537A>G p.S513G | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100314541; called by muse, mutect2, varscan2
- SEPTIN6 | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100595876; called by muse, mutect2, varscan2
- SERPINB11 | c.60C>A p.N20K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0.23); catalogued as COSV101236355; called by muse, mutect2, varscan2
- SESTD1 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 25/93 reads (27%) | catalogued as rs1241702828, COSV100090984, COSV58931471; called by muse, mutect2, varscan2
- SETDB1 | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.009); catalogued as COSV99646044; called by muse, mutect2
- SEZ6L | c.2175C>G p.I725M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV99962869, COSV99963137; called by muse, mutect2, varscan2
- SLAMF6 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100924959; called by muse, mutect2, varscan2
- SLC29A3 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.272); catalogued as COSV100928609; called by muse, mutect2, varscan2
- SLC2A1 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as COSV100995994; called by muse, mutect2, varscan2
- SLC5A7 | c.1556C>A p.A519E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99887388; called by muse, mutect2, varscan2
- SLCO4C1 | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.085); catalogued as COSV100196004; called by muse, mutect2, varscan2
- SNAP91 | c.1997C>G p.S666W | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52119908, COSV99536927; called by muse, mutect2, varscan2
- SPATA2 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99193011; called by muse, mutect2, varscan2
- SPIN2B | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99328221; called by muse, mutect2, varscan2
- STYK1 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99312338; called by muse, mutect2, varscan2
- TAB3 | c.1237G>T p.G413W | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99916929; called by muse, mutect2, varscan2
- TCERG1 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as rs769435463, COSV57036240, COSV99695383; called by muse, mutect2, varscan2
- TCERG1 | c.2259G>T p.K753N | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99695385; called by muse, mutect2, varscan2
- TENM1 | c.6571C>T p.L2191F | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as COSV100951215; called by muse, mutect2, varscan2
- TGFBRAP1 | c.627G>T p.R209S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as rs1248968590, COSV99305639; called by muse, mutect2, varscan2
- TMLHE | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100545162; called by muse, mutect2, varscan2
- TMPRSS15 | c.963A>T p.E321D | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV99519578; called by muse, mutect2, varscan2
- TNFRSF21 | c.474G>C p.K158N | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99730362; called by muse, mutect2, varscan2
- TNNT1 | c.369A>T p.E123D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV52571427, COSV99403085; called by muse, mutect2, varscan2
- TRIM28 | c.1748A>T p.E583V | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as COSV99449532; called by muse, mutect2, varscan2
- TRIM48 | c.375C>A p.S125R | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs1475429327, COSV101338374; called by muse, mutect2
- TRPC5 | c.1609C>A p.Q537K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99461078, COSV99463180; called by muse, mutect2, varscan2
- TRRAP | c.8885A>G p.N2962S (on ENST00000359863 / NM_001244580.1; = p.N2944S on NM_003496.3) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV100723167; called by muse, mutect2, varscan2
- TTC26 | c.701A>G p.N234S | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV100571202; called by muse, mutect2, varscan2
- TTI1 | c.2099A>G p.N700S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.341); catalogued as COSV100989783; called by muse, mutect2, varscan2
- TXNDC16 | c.1065A>T p.E355D | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99909753; called by muse, mutect2, varscan2
- UBA1 | c.2445G>T p.Q815H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV100256187; called by muse, mutect2, varscan2
- UBE2J1 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV101470296; called by muse, mutect2, varscan2
- UPF3B | c.1019A>G p.E340G (on ENST00000276201 / NM_080632.3; = p.E327G on NM_023010.3) | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV99352421; called by muse, mutect2, varscan2
- UPRT | c.562G>C p.G188R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100974563, COSV100974571, COSV64912752; called by muse, mutect2, varscan2
- USF3 | c.5381A>T p.Y1794F | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100325899; called by muse, mutect2, varscan2
- USF3 | c.4251A>T p.E1417D | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV100325902; called by muse, mutect2, varscan2
- USP29 | c.2017C>A p.P673T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as COSV99518828; called by muse, mutect2, varscan2
- USP29 | c.2018C>A p.P673Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as rs1402773020, COSV99518830; called by muse, mutect2, varscan2
- VIT | c.1399C>A p.L467I (on ENST00000389975 / NM_001177969.1; = p.L482I on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101007793; called by muse, mutect2, varscan2
- VPS13B | c.5335G>C p.G1779R | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as COSV100663941; called by muse, mutect2, varscan2
- WDFY3 | c.8167C>G p.L2723V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99886138; called by muse, mutect2, varscan2
- WDFY3 | c.3505G>T p.E1169* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV55701476, COSV99886142; called by muse, mutect2, varscan2
- WT1 | c.578C>A p.A193E | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.257); catalogued as COSV100189181, COSV60072025; called by muse, mutect2
- WWC3 | c.2602G>T p.D868Y | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101081943; called by muse, varscan2
- WWC3 | c.2743C>T p.R915* | Nonsense Mutation (SNP) | VAF 21/165 reads (13%) | catalogued as rs1230268831, COSV101081946; called by muse, varscan2
- XCL1 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100892217; called by muse, mutect2, varscan2
- ZFHX4 | c.3262G>A p.A1088T | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1419739322, COSV50812243; called by muse, mutect2, varscan2
- ZIM3 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as COSV99518831; called by muse, mutect2, varscan2
- ZNF154 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101377558; called by muse, mutect2, varscan2
- ZNF208 | c.2330A>G p.Y777C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV68113416; called by muse, mutect2, varscan2
- ZNF25 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100224823; called by muse, mutect2
- ZNF274 | c.1091C>G p.S364C (on ENST00000610905; = p.S259C on NM_016324.3) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.533); catalogued as COSV100465643; called by muse, mutect2, varscan2
- ZNF382 | c.977G>C p.C326S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99498169; called by muse, mutect2, varscan2
- ZNF569 | c.1898C>A p.P633H | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs763734410, COSV100386682; called by muse, mutect2, varscan2
- ZNF613 | c.1037G>T p.C346F (on ENST00000293471 / NM_001031721.4; = p.C310F on NM_024840.4) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53274385, COSV99523095; called by muse, mutect2, varscan2
- ZNF616 | c.1940A>G p.H647R | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100348604; called by muse, mutect2, varscan2
- C3orf22 | c.400del p.A134Qfs*30 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- COLQ | c.1253A>T p.D418V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- H2AC11 | c.391dup p.*131Lfs*12 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- HBG2 | c.216G>T p.L72F | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2
- IGHV1OR21-1 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- NLRP7 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- SETD2 | c.7267del p.E2423Kfs*27 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- SUZ12 | c.562_563delinsA p.L188Mfs*2 | Frame Shift Del (DEL) | VAF 14/95 reads (15%) | called by pindel, varscan2*
- TXLNA | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC10 | c.1863C>G p.L621= (on ENST00000372530 / NM_001198934.2; = p.L593= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as rs143415707, COSV99768150; called by muse, mutect2, varscan2
- ACTBL2 | c.201C>A p.T67= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV101379433; called by muse, mutect2, varscan2
- ACY3 | c.945G>T p.P315= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs139551384, COSV54830057; called by muse, mutect2, varscan2
- AGTR2 | c.789G>C p.L263= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as COSV100903638; called by muse, mutect2, varscan2
- AKR7A2 | c.477G>A p.L159= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs564398632, COSV99352210; called by muse, mutect2
- AL645922.1 | c.57C>T p.D19= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100191572; called by muse, mutect2, varscan2
- ANK2 | c.11253G>A p.Q3751= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV52194110; called by muse, mutect2, varscan2
- ARFGEF1 | c.4296C>T p.F1432= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99145440; called by muse, mutect2, varscan2
- ATP12A | c.1803G>T p.V601= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs752081861, COSV54513791, COSV54525836; called by muse, mutect2, varscan2
- BRD9 | c.687C>T p.I229= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as COSV60244808; called by muse, mutect2, varscan2
- CBLL1 | c.267T>C p.L89= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs1379233157, COSV99756024; called by muse, mutect2, varscan2
- CCDC190 | c.726A>G p.T242= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100905848; called by muse, mutect2, varscan2
- CCNF | c.915C>G p.L305= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99564282; called by muse, mutect2, varscan2
- CD163L1 | c.474G>A p.V158= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1325007811, COSV100550805; called by muse, mutect2, varscan2
- CNTN1 | c.2394A>G p.V798= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100751702; called by muse, mutect2, varscan2
- CNTNAP3 | c.1794A>T p.R598= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs777684638, COSV99905806; called by muse, mutect2, varscan2
- COL22A1 | c.543C>G p.L181= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100281216; called by muse, mutect2, varscan2
- COL6A6 | c.5067G>T p.G1689= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV62033089; called by muse, mutect2, varscan2
- CPE | c.1167G>C p.A389= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs988153629, COSV101291754, COSV68580563; called by muse, mutect2, varscan2
- DCC | c.1269A>T p.P423= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV100503611; called by muse, mutect2, varscan2
- DHODH | c.42G>C p.V14= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99537070; called by muse, varscan2
- DHX38 | c.2820C>T p.T940= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as rs1037233753, COSV99194667; called by muse, mutect2, varscan2
- DNAH5 | c.12477A>T p.A4159= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99455315; called by muse, mutect2
- DOCK11 | c.5310C>A p.G1770= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs936358128, COSV99354989; called by muse, mutect2, varscan2
- DOCK8 | c.6270A>G p.K2090= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV101210107; called by muse, mutect2, varscan2
- EDEM2 | c.27C>T p.L9= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs752539530, COSV100993703, COSV100993859; called by muse, mutect2, varscan2
- F8 | c.4110C>G p.T1370= | Silent (SNP) | VAF 40/259 reads (15%) | catalogued as COSV100812095; called by muse, mutect2, varscan2
- FAM111A | c.39C>G p.V13= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100659497; called by muse, mutect2, varscan2
- FAM209A | c.515G>A p.*172= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV99711786; called by muse, mutect2, varscan2
- FGF21 | c.153A>G p.T51= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99711572; called by muse, mutect2, varscan2
- FRY | c.1278T>C p.T426= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs377698779, COSV100970029; called by muse, mutect2, varscan2
- FUT10 | c.768G>C p.L256= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV100161874, COSV59454378; called by muse, mutect2
- GRM6 | c.1509C>G p.A503= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99180031; called by mutect2, varscan2
- GYG2 | c.1356C>T p.A452= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV58551378; called by muse, mutect2, varscan2
- HEG1 | c.2676A>G p.Q892= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs377517994, COSV100231057; called by muse, mutect2, varscan2
- HPS4 | c.207C>T p.D69= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs1215916691, COSV100404777; called by muse, mutect2, varscan2
- HSPG2 | c.9354C>A p.P3118= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs374611258, COSV101013577; called by muse, mutect2, varscan2
- IL5 | c.75C>A p.P25= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV99185066; called by muse, mutect2, varscan2
- INO80C | c.69G>A p.R23= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs767425631, COSV99358577; called by mutect2, varscan2
- KEL | c.966G>T p.A322= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as rs149527899, COSV100787344; called by muse, mutect2, varscan2
- LARP6 | c.384C>T p.S128= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs141487882; called by muse, mutect2, varscan2
- LCE5A | c.150C>A p.S50= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV100524348; called by muse, mutect2, varscan2
- LMBR1 | c.987A>G p.G329= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100626928; called by mutect2, varscan2
- LPA | c.3816G>A p.Q1272= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100308291; called by muse, mutect2, varscan2
- MAP3K13 | c.162A>T p.T54= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99408146; called by muse, mutect2
- MERTK | c.1227G>C p.P409= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs1384330473, COSV54924301, COSV99775446; called by muse, mutect2, varscan2
- MUC16 | c.11154G>A p.K3718= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV101202083; called by muse, mutect2, varscan2
- NEPRO | c.60G>C p.A20= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs760544288, COSV100075192, COSV58723846; called by muse, mutect2, varscan2
- NHSL2 | c.876C>A p.A292= (on ENST00000510661; = p.A658= on NM_001013627.2) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV101030400; called by muse, mutect2, varscan2
- OR10G4 | c.396C>A p.T132= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as rs1440843926, COSV100305040; called by muse, mutect2, varscan2
- OR4A47 | c.738C>T p.V246= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as rs1179080125, COSV101487121; called by muse, mutect2, varscan2
- OSTN | c.75C>A p.V25= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100174381; called by muse, mutect2
- PARP11 | c.981C>T p.N327= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs754923500, COSV99959318; called by muse, mutect2, varscan2
- PCDHA10 | c.1566G>T p.L522= | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as rs1554150351, COSV100255663; called by muse, mutect2, varscan2
- PCDHB15 | c.636G>A p.L212= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99179302; called by muse, mutect2, varscan2
- PHC3 | c.2571A>T p.P857= (on ENST00000494943 / NM_001308116.2; = p.P869= on NM_024947.4) | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV101520199; called by muse, mutect2
- PKHD1L1 | c.11449C>T p.L3817= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV101007019; called by muse, mutect2, varscan2
- PLBD2 | c.1083C>A p.T361= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99785547; called by muse, mutect2, varscan2
- POLA1 | c.3660G>T p.V1220= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100985852; called by muse, mutect2, varscan2
- PRKACG | c.132C>T p.F44= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs1407907592, COSV55242298; called by muse, mutect2, varscan2
- PRLR | c.1722A>G p.E574= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV99184869; called by muse, mutect2, varscan2
- PSG2 | c.939C>A p.S313= | Silent (SNP) | VAF 42/202 reads (21%) | catalogued as COSV100283332, COSV61544617; called by muse, mutect2, varscan2
- RASA1 | c.1446G>T p.L482= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV99171316; called by muse, mutect2, varscan2
- RBM42 | c.594T>G p.P198= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99387280; called by muse, mutect2, varscan2
- RPL7L1 | c.396C>T p.V132= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs761620887, COSV100491829; called by muse, mutect2, varscan2
- RPS6KA6 | c.1335T>C p.H445= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- SLC25A16 | c.900C>G p.L300= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV99770296; called by muse, mutect2, varscan2
- SLC44A2 | c.483C>G p.V161= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100213516; called by muse, mutect2, varscan2
- SNRNP35 | c.315G>C p.V105= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100644605; called by muse, mutect2, varscan2
- SP140 | c.2310C>T p.V770= | Silent (SNP) | VAF 21/185 reads (11%) | catalogued as COSV100614029, COSV100614158; called by muse, mutect2, varscan2
- SPATS2L | c.348G>A p.S116= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs372973345, COSV100660801, COSV62346808; called by muse, varscan2
- TBC1D22B | c.1452G>T p.L484= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV100996967; called by muse, mutect2, varscan2
- TLR8 | c.351A>T p.T117= (on ENST00000218032 / NM_138636.5; = p.T135= on NM_016610.4) | Silent (SNP) | VAF 43/186 reads (23%) | catalogued as COSV99487381; called by muse, mutect2, varscan2
- TMEM86A | c.399C>T p.A133= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV99773723, COSV99773896; called by muse, mutect2, varscan2
- TNR | c.2385T>C p.S795= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99692053; called by muse, mutect2, varscan2
- VEZF1 | c.1464A>T p.L488= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV99365952; called by muse, mutect2, varscan2
- VSIG1 | c.156A>T p.R52= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV99480516; called by muse, mutect2, varscan2
- VSIG1 | c.546C>A p.I182= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV54257360, COSV99480517; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501560 G>T | 5'Flank (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- ECPAS | chr9:111484403 C>G | 5'Flank (SNP) | VAF 6/19 reads (32%) | catalogued as COSV52193781, COSV99399503; called by muse, mutect2, varscan2
- MAPKAP1 | c.498+5526T>A | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- MRPS17P9 | n.215C>A | RNA (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- MTUS2 | c.-15A>T | 5'UTR (SNP) | VAF 14/51 reads (27%) | catalogued as COSV101462406; called by muse, mutect2, varscan2
